Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A1H6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A1H6-01B (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

ICD-0-3
Adenocarcinoma, NOS 8140/3
Site: Cervix, NOS C53.9

2/1/11

Case Number :

Reviewed:		1/28/11

Diagnosis:

A: Uterus, cervix, radical hysterectomy, bilateral salpingectomy, and parametrectomy

Location of tumor: tumor circumferentially involves the cervix, including the endocervix

Histologic type: endocervical adenocarcinoma

Histologic grade: well differentiated

Tumor size: 2.5 cm

Extent of invasion:

Cervical invasion: outer half

Depth: 8 mm Wall thickness: 1.2 cm

Percent: 67% (A2)

Deep margin involvement: absent

Lower uterine segment involvement: absent

Parametrium: no tumor seen

Cervical/vaginal margin and distance: free of tumor (8 mm to closest cervical vaginal cuff margin)

Lymphovascular Space Invasion: absent

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 20

Adnexal involvement: right and left fallopian tubes, no tumor seen

Other Pathologic findings:

- Endometrium shows atrophic endometrium.

- Adenocarcinoma in situ is present adjacent to invasive endocervical adenocarcinoma in the cervix.

[page 2 of 4]
- Myometrium with no significant pathologic abnormality.

AJCC Pathologic stage: pT1b1 pN0 pMx

FIGO Stage grouping: IB1

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Fallopian tube, right, salpingectomy:

- No tumor seen.

Fallopian tube, left, salpingectomy:

- No tumor seen.

B: Right pelvic lymph node, dissection

- Ten lymph nodes, no tumor seen (0/10).

C: Left pelvic lymph node, dissection

- Ten lymph nodes, no tumor seen (0/10).

Clinical History:

The patient is with cervical cancer.

Gross Description:

Specimen A is additionally labeled "uterus, cervix, parametrial tissue bilateral"

Specimen fixation: Formalin

Specimen type: Radical hysterectomy

Adnexa: Bilateral fallopian tubes present with specimen

Weight: 104.9 grams

Shape: Pear

Dimensions:

Height: 9.0 cm

Anterior to posterior width: 4.5 cm

Breadth at fundus: 6.0 cm

Serosa: Tan/pink without masses. The anterior surface was inked blue, posterior surface inked black.

Cervix:

[page 3 of 4]
Tumor size: Not identified grossly

Other features: Cervix demonstrates recent surgical changes, possibly from previous cone biopsy.

Endometrium:

Length of endometrial cavity: 3.8 cm

Width of endometrial cavity at fundus: 2.4 cm

Thickness of lining: 0.1 cm

Other findings: None

Myometrium:

Thickness of wall: 1.5 cm

Other findings: Sectioning demonstrates no masses

Adnexa:

Right ovary: Not present

Right fallopian tube

Measurement: 8.6 cm x 0.4 cm

Other findings Fimbriated end present

Left ovary Not present

Left fallopian tube

Measurement: 8.7 cm x 0.4 cm

Other findings Fimbriated end present

Block Summary:

Inking: Anterior/blue, posterior/black

A1 - anterior cervix 12 to 1

A2 - anterior cervix 1 to 2

A3 - anterior cervix 2 to 3

A4 - anterior cervix, additional lateral parametrial tissue

A5 - anterior cervix 11 to 12

A6 - anterior cervix 10 to 11

A7 - anterior cervix 9 to 10 o' clock

A8 - additional 9 o' clock tissue

A9 - anterior cervix 3 to 4 o' clock

A10-A11 - anterior cervix 4 to 5 o' clock, bisected

A12 - anterior cervix 5 to 6 o' clock

A13 - anterior cervix 6 to 7 o' clock

A14 - anterior cervix 7 to 8 o' clock

A15 - anterior cervix 8 to 9 o' clock

A16 - left parametrial tissue, adjacent to cervix 3 to 6 o' clock

A17 - right parametrial tissue, adjacent to cervix 6 to 9 o' clock

A18 - right parametrial tissue, adjacent to cervix 9 to 12 o' clock

[page 4 of 4]
A19 - right parametrial tissue, adjacent to cervix 9 to 12 o' clock
A20 - right parametrial tissue, adjacent to lower uterine segment
A21 - left parametrial tissue, adjacent to lower uterine segment
A22 - anterior lower uterine segment
A23-A24 - posterior lower uterine segment, bisected
A25 - anterior mid corpus
A26 - posterior mid corpus
A27 - right fallopian tube
A28 - left fallopian tube

Specimen B:

SITE: "Right pelvic node"
METHOD: Lymph node dissection
MEASURE: 5.9 x 5.4 x 1.6 cm
COMMENT: Fibroadipose tissue with node candidates
BLOCK#: B1 - Three lymph node candidates
B2 - Four lymph node candidates
B3 - Four lymph node candidates
B4 - Two lymph node candidates
Fibroadipose tissue remains

Specimen: C

SITE: "Right pelvis"
METHOD: Lymph node dissection
MEASURE: 5.8 x 4.0 x 1.8 cm
COMMENT: Yellow/tan fibroadipose tissue admixed with lymph node candidates
BLOCK: C1 - Three lymph node candidates
C2 - Four lymph node candidates
C3 - Four lymph node candidates
Fibroadipose tissue remains

Grossing Pathologist:

Light Microscopy:
Light microscopic examination is performed by Dr.

Signature
Resident Physician:

Attending Pathologist : I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 22783195-11aa-4288-84bc-5364f6981c65 (TCGA-EX-A1H6.C0A44D8D-EE10-45EF-8B23-23A2E793E5D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).